Somatic mutation profile of tumor specimen d0ce3c06-9c4c-41bd-b583-9254b0 (aliquot d0ce3c06-9c4c-41bd-b583-9254b0_D6_1) from CPTAC case 05BR029, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.9 years (22,599 days).
Specimen d0ce3c06-9c4c-41bd-b583-9254b0: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 203e983b-2abc-43e1-8ab7-c058d2d02374.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen de477850-d854-4df8-8a84-67224c (Blood Derived Normal), aliquot de477850-d854-4df8-8a84-67224c_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1704844-030e-408e-99d7-defcea7fb9e1

The open-access MAF lists 528 somatic variants for this specimen: 336 protein-altering or splice-affecting, 109 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 245, Silent 109, Frame Shift Del 48, Intron 37, 3'UTR 16, Nonsense Mutation 15, RNA 13, Splice Site 10, Frame Shift Ins 10, 5'UTR 7, Splice Region 6, 3'Flank 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.2923C>T p.R975W | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795307; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FANCE | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 45/180 reads (25%) | catalogued as rs121434506, CM003676; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs111033284, CM071027, CM1110176, COSV68683548; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NOTCH2 | c.6909del p.I2304Lfs*2 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | catalogued as rs771237928; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RECQL | c.120del p.V41Sfs*2 | Frame Shift Del (DEL) | VAF 96/428 reads (22%) | catalogued as rs745659712, COSV59084411; ClinVar: pathogenic; called by mutect2, varscan2
- ACAP3 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as rs369561716; called by muse, mutect2, varscan2
- ADAMTSL4 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99646677; called by muse, mutect2
- AMMECR1 | c.246del p.I83Sfs*80 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | catalogued as rs1179112821; called by mutect2, pindel, varscan2
- ANKRD31 | c.1233G>C p.K411N | Missense Mutation (SNP) | VAF 78/138 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV57160523; called by muse, mutect2, varscan2
- ANKRD35 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as rs201815402, COSV62909548, COSV62911775, COSV99053003; called by muse, mutect2, varscan2
- ANKRD60 | c.313dup p.E105Gfs*45 | Frame Shift Ins (INS) | VAF 76/194 reads (39%) | catalogued as rs1049113698; called by mutect2, varscan2
- APPBP2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as rs1487790842; called by muse, mutect2, varscan2
- ARFGEF3 | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs754312669; called by muse, varscan2
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 44/147 reads (30%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- BCL6 | c.1418del p.P473Rfs*117 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as COSV51655892; called by mutect2, pindel, varscan2
- CACNA1A | c.6675del p.P2227Rfs*45 (on ENST00000614285; = p.P2227Rfs*285 on NM_000068.4) | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs1555730604, COSV100801821; called by mutect2, pindel, varscan2
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 28/50 reads (56%) | catalogued as rs745648688, COSV53168096; called by mutect2, pindel, varscan2
- CELSR3 | c.9167C>T p.T3056M | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.791); catalogued as rs759205227, COSV51038812; called by muse, mutect2, varscan2
- CFLAR | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs371340033; called by muse, mutect2, varscan2
- CHAD | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs773703642; called by muse, mutect2, varscan2
- COASY | c.537del p.V180Wfs*47 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | catalogued as COSV55900587; called by mutect2, pindel, varscan2
- COL4A6 | c.1378C>T p.L460F | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.799); catalogued as COSV57863115; called by muse, varscan2
- CPT1B | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777526020, COSV56415085; called by muse, mutect2, varscan2
- DGAT1 | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as rs1554847144, COSV60049017; called by muse, mutect2, varscan2
- DHX58 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs369279500; called by muse, mutect2, varscan2
- DLG5 | c.4493T>G p.L1498R | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs759190403; called by muse, mutect2, varscan2
- DNAAF3 | c.941T>C p.V314A (on ENST00000524407 / NM_001256715.2; = p.V361A on NM_178837.4) | Missense Mutation (SNP) | VAF 67/94 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs777418027; called by muse, mutect2, varscan2
- DNAH6 | c.5683A>G p.M1895V | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV52867541; called by muse, mutect2, varscan2
- DNAH7 | c.8737G>A p.G2913R | Missense Mutation (SNP) | VAF 54/68 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368479769, COSV56781668; called by muse, mutect2, varscan2
- DNPEP | c.192G>C p.E64D | Missense Mutation (SNP) | VAF 83/131 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99815206; called by muse, mutect2, varscan2
- DOT1L | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs760542574, COSV67108311; called by muse, mutect2, varscan2
- ELAVL4 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV63916278; called by muse, mutect2, varscan2
- FBLN1 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs1465762131; called by muse, mutect2, varscan2
- FNBP1 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1022291851; called by muse, mutect2
- FRAS1 | c.3544C>T p.H1182Y | Missense Mutation (SNP) | VAF 82/134 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV53614902; called by muse, mutect2, varscan2
- GALNT5 | c.384T>A p.H128Q | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs776627268; called by muse, mutect2, varscan2
- GAS6 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 77/154 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs373825026; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 40/158 reads (25%) | catalogued as rs763147690; called by mutect2, varscan2
- GOLGA8K | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as rs765444810; called by muse, mutect2, varscan2
- GRIPAP1 | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs782100480; called by muse, mutect2, varscan2
- HAGH | c.638del p.P213Rfs*61 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | catalogued as rs751524326; called by mutect2, pindel, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 42/131 reads (32%) | catalogued as COSV100625709; called by mutect2, varscan2
- HEATR6 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 36/74 reads (49%) | catalogued as rs777970457; called by muse, mutect2, varscan2
- HMMR | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs775035048, COSV62373999; called by muse, mutect2, varscan2
- HPGDS | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as rs1261445522; called by muse, mutect2, varscan2
- IDH3B | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs374735773; called by muse, mutect2, varscan2
- IDH3G | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs199721612; called by muse, mutect2, varscan2
- IGHMBP2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746259825; called by muse, mutect2, varscan2
- IL13RA1 | c.1268A>G p.K423R | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as rs759923231; called by muse, mutect2, varscan2
- IPO13 | c.2495C>A p.P832H | Missense Mutation (SNP) | VAF 81/207 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.05); catalogued as rs758899536; called by muse, mutect2, varscan2
- IQCB1 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 214/562 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.976); catalogued as rs146832128, COSV60437015; called by muse, mutect2
- IQSEC3 | c.2603G>A p.R868H (on ENST00000538872 / NM_001170738.2; = p.R565H on NM_015232.1) | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs545050878, COSV58281377; called by muse, mutect2, varscan2
- ITGAM | c.2395C>T p.R799W (on ENST00000648685 / NM_001145808.2; = p.R798W on NM_000632.4) | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs1314053426; called by muse, mutect2, varscan2
- ITPR2 | c.8003C>T p.A2668V | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as rs541786341, COSV67265133; called by muse, mutect2, varscan2
- KAT7 | c.151C>A p.Q51K | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV52016074; called by muse, mutect2, varscan2
- KIAA0319L | c.2602C>T p.R868W | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as rs749736814, COSV57845785; called by muse, mutect2, varscan2
- KLHL10 | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53175333; called by muse, mutect2, varscan2
- KLHL6 | c.844A>G p.R282G | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs1178385825; called by muse, mutect2, varscan2
- LCAT | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 72/117 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780824776, CM053948; called by muse, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 30/44 reads (68%) | catalogued as COSV65473126, COSV65473260; called by mutect2, varscan2
- LIMS2 | c.256C>T p.R86C (on ENST00000355119 / NM_001161403.3; = p.R110C on NM_017980.4) | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs757640443; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMTK3 | c.4131del p.E1378Rfs*106 | Frame Shift Del (DEL) | VAF 23/33 reads (70%) | catalogued as rs758225154; called by mutect2, varscan2
- LPCAT3 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 123/177 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV54645897; called by muse, mutect2, varscan2
- LYPLA1 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV57606359; called by muse, mutect2, varscan2
- MAGEE1 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1385771340; called by muse, mutect2, varscan2
- MAP2 | c.4876C>T p.P1626S | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV52292803; called by muse, mutect2, varscan2
- METTL25 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779378824; called by muse, mutect2, varscan2
- MGAM | c.4656G>C p.T1552= | Splice Region (SNP) | VAF 138/254 reads (54%) | catalogued as COSV72075157, COSV72075740; called by muse, mutect2, varscan2
- MMP17 | c.1597G>T p.A533S | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100861892; called by muse, varscan2
- MPP2 | c.1067A>G p.D356G (on ENST00000461854 / NM_001278372.2; = p.D332G on NM_005374.5) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs868258635; called by muse, mutect2, varscan2
- MUC17 | c.4754T>C p.V1585A | Missense Mutation (SNP) | VAF 78/262 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1262745818; called by mutect2, varscan2
- MYH6 | c.3808C>T p.R1270C | Missense Mutation (SNP) | VAF 147/257 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371849826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYRF | c.1612G>C p.E538Q (on ENST00000278836 / NM_001127392.3; = p.E529Q on NM_013279.4) | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53885903; called by muse, mutect2, varscan2
- NBEA | c.8065A>G p.N2689D | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs769588176; called by muse, mutect2, varscan2
- NFASC | c.2689C>T p.R897C (on ENST00000339876 / NM_001378329.1; = p.R1000C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1309632528, COSV58367643; called by muse, mutect2, varscan2
- NFKBID | c.467C>A p.P156Q (on ENST00000396901; = p.P308Q on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/121 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV61727733; called by muse, mutect2, varscan2
- NRK | c.2344del p.I782Lfs*66 | Frame Shift Del (DEL) | VAF 29/146 reads (20%) | catalogued as COSV54591328; called by mutect2, pindel, varscan2
- OR4K15 | c.804C>G p.I268M (on ENST00000305051; = p.I244M on NM_001005486.1) | Missense Mutation (SNP) | VAF 60/93 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59303617; called by muse, varscan2
- OR5H14 | c.464A>G p.H155R | Missense Mutation (SNP) | VAF 118/380 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774514186; called by muse, varscan2
- P4HB | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466684118, COSV58942089; called by muse, mutect2, varscan2
- PAK1 | c.1357A>G p.M453V | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99583535; called by muse, mutect2, varscan2
- PAK4 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs749373073; called by muse, mutect2, varscan2
- PCDHGB1 | c.1608del p.A537Rfs*6 | Frame Shift Del (DEL) | VAF 36/99 reads (36%) | catalogued as rs1324085852, COSV53992573; called by mutect2, pindel, varscan2
- PDE6A | c.1730C>T p.T577M | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs765007196, COSV54929266; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDHA1 | c.607del p.Q203Rfs*50 | Frame Shift Del (DEL) | VAF 159/471 reads (34%) | catalogued as COSV58826394, COSV58832146; called by mutect2, pindel, varscan2
- PDZD7 | c.2182del p.L728Sfs*25 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | catalogued as rs1162586274; called by mutect2, pindel, varscan2
- PIWIL2 | c.2393del p.K798Sfs*5 | Frame Shift Del (DEL) | VAF 14/25 reads (56%) | catalogued as COSV63249731; called by mutect2, pindel, varscan2
- PLIN2 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs896892781, COSV52802931, COSV52804379; called by muse, varscan2
- PLK2 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); catalogued as rs55645589; called by muse, mutect2, varscan2
- PLOD1 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 95/155 reads (61%) | catalogued as rs1308628256, COSV52144493, COSV52145416; called by muse, mutect2, varscan2
- POU3F4 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs867054269, CD093383, COSV64539637; called by muse, mutect2, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | catalogued as rs540232176; called by mutect2, varscan2
- PRKDC | c.7493T>C p.I2498T | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs1322147412; called by muse, mutect2
- QRICH2 | c.4235C>T p.A1412V | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs751887084, COSV53152842; called by muse, mutect2, varscan2
- RALB | c.18A>G p.S6= | Splice Region (SNP) | VAF 8/128 reads (6%) | catalogued as rs892107765; called by muse, mutect2
- RALB | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760095690, COSV55604149; called by muse, mutect2, varscan2
- RIMS2 | c.4063G>A p.E1355K | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.763); catalogued as COSV51667634; called by muse, mutect2, varscan2
- RIPOR2 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 73/148 reads (49%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.522); catalogued as rs779460974, COSV52428849, COSV52430628; called by muse, mutect2, varscan2
- SBNO2 | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs770824881, COSV62321815; called by muse, mutect2, varscan2
- SEMA3C | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as rs1348895445; called by muse, mutect2, varscan2
- SEMA5B | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs139012400, COSV99530446; called by muse, mutect2, varscan2
- SH2B2 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.493); catalogued as COSV60825766; called by muse, varscan2
- SIGLEC9 | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 125/191 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs1158278510, COSV51588371; called by muse, mutect2, varscan2
- SIPA1L3 | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 98/173 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as COSV55917438; called by muse, mutect2, varscan2
- SNX9 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV101093840; called by muse, mutect2, varscan2
- STAB1 | c.3364dup p.R1122Pfs*37 | Frame Shift Ins (INS) | VAF 13/27 reads (48%) | catalogued as rs563085224; called by mutect2, varscan2
- STARD9 | c.3290A>G p.D1097G | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.154); catalogued as rs969137637; called by muse, mutect2, varscan2
- STXBP2 | c.1616T>C p.M539T | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs886054705; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.14258T>G p.L4753R (on ENST00000367255 / NM_182961.4; = p.L4682R on NM_033071.3) | Missense Mutation (SNP) | VAF 79/378 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.146); catalogued as COSV54968252; called by muse, mutect2, varscan2
- TAF11 | c.622dup p.I208Nfs*26 | Frame Shift Ins (INS) | VAF 49/170 reads (29%) | catalogued as rs1385487890; called by mutect2, varscan2
- TANC2 | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 40/127 reads (31%) | catalogued as COSV67338282; called by muse, mutect2, varscan2
- TARBP1 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs866520840; called by muse, mutect2, varscan2
- TENM3 | c.5894G>C p.R1965T | Missense Mutation (SNP) | VAF 103/187 reads (55%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.447); catalogued as COSV69313990; called by muse, mutect2, varscan2
- TENM4 | c.2201G>A p.G734D | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565378919; called by muse, mutect2, varscan2
- TET2 | c.4147A>G p.R1383G | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54404268; called by muse, mutect2, varscan2
- THAP5 | c.297del p.K99Nfs*25 (on ENST00000415914 / NM_001130475.3; = p.K57Nfs*25 on NM_182529.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/196 reads (12%) | catalogued as rs745348876; called by mutect2, varscan2
- THBS4 | c.89-2A>G p.X30_splice | Splice Site (SNP) | VAF 59/93 reads (63%) | catalogued as rs1344373465; called by muse, mutect2, varscan2
- TLL1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV50268252; called by muse, mutect2, varscan2
- TNKS2 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as rs764106777; called by muse, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 52/110 reads (47%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TP53 | c.649del p.V217Wfs*30 | Frame Shift Del (DEL) | VAF 115/220 reads (52%) | catalogued as CM035961, COSV53163407; called by mutect2, pindel, varscan2
- TRPM3 | c.3085G>A p.A1029T (on ENST00000357533 / NM_001366142.2; = p.A872T on NM_020952.6) | Missense Mutation (SNP) | VAF 120/306 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs1036752298; called by muse, mutect2, varscan2
- TSHZ3 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1278628782, COSV53664488; called by muse, mutect2, varscan2
- TSPAN10 | c.456del p.L154Cfs*19 (on ENST00000574882 / NM_001290212.1; = p.L116Cfs*19 on NM_031945.4) | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | catalogued as rs771262491, COSV100148738, COSV60773593; called by pindel, varscan2
- TUBGCP6 | c.3551G>A p.R1184Q | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.806); catalogued as rs139409990; called by muse, mutect2, varscan2
- VANGL2 | c.208del p.E70Kfs*5 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | catalogued as COSV63604478; called by mutect2, pindel, varscan2
- VWA5A | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.403); catalogued as rs1565615812; called by muse, mutect2, varscan2
- WDR13 | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV54331823; called by muse, mutect2, varscan2
- ZBTB7B | c.236C>T p.T79M (on ENST00000292176; = p.T113M on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs753049116; called by muse, mutect2, varscan2
- ZFP57 | c.687G>T p.R229S | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs574779981; called by muse, mutect2, varscan2
- ZFYVE26 | c.3974C>T p.P1325L | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs747346400; called by muse, mutect2, varscan2
- ZMYM6 | c.3832T>G p.F1278V | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64120625; called by muse, mutect2, varscan2
- ZNF692 | c.1062C>G p.I354M | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs780345763; called by muse, mutect2, varscan2
- ABCA1 | c.1299G>T p.M433I | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCA12 | c.4647C>A p.F1549L (on ENST00000272895 / NM_173076.3; = p.F1231L on NM_015657.3) | Missense Mutation (SNP) | VAF 101/144 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ACACB | c.1479G>C p.K493N | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ADAMTS10 | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADARB1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADCK5 | c.483del p.E162Sfs*9 | Frame Shift Del (DEL) | VAF 46/217 reads (21%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.2337G>T p.R779S | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AFF2 | c.1016A>G p.K339R | Missense Mutation (SNP) | VAF 112/200 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHNAK | c.14317G>A p.G4773S | Missense Mutation (SNP) | VAF 105/304 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP1 | c.2521G>C p.E841Q | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AKAP12 | c.4769C>T p.A1590V | Missense Mutation (SNP) | VAF 101/315 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- AKAP9 | c.6289dup p.M2097Nfs*7 (on ENST00000359028; = p.M2065Nfs*7 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 99/389 reads (25%) | called by mutect2, pindel, varscan2
- ALKBH3 | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 115/159 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- ALOXE3 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ALPK2 | c.3962T>C p.I1321T | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- ANGPTL1 | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 120/341 reads (35%) | called by muse, mutect2, varscan2
- ANKFN1 | c.1444A>G p.T482A | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ANKMY1 | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 84/142 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APOL2 | c.967T>G p.F323V | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP22 | c.2081C>A p.A694D | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARNTL2 | c.1775-1G>T p.X592_splice | Splice Site (SNP) | VAF 35/234 reads (15%) | called by muse, mutect2, varscan2
- ART1 | c.34G>C p.V12L | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASAH1 | c.575G>T p.W192L | Missense Mutation (SNP) | VAF 156/244 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ASF1A | c.202G>T p.G68* | Nonsense Mutation (SNP) | VAF 53/237 reads (22%) | called by muse, mutect2, varscan2
- ASNSD1 | c.292T>C p.Y98H | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATG16L1 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 92/180 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 88/170 reads (52%) | called by pindel, varscan2
- B3GLCT | c.823del p.T275Hfs*61 | Frame Shift Del (DEL) | VAF 154/522 reads (30%) | called by pindel, varscan2
- BCLAF1 | c.1858T>C p.Y620H | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- BECN1 | c.1336C>G p.Q446E | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- C5 | c.4763-2A>G p.X1588_splice | Splice Site (SNP) | VAF 88/296 reads (30%) | called by muse, mutect2
- CADPS2 | c.2989C>T p.P997S | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALU | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC138 | c.852del p.K284Nfs*3 | Frame Shift Del (DEL) | VAF 37/85 reads (44%) | called by mutect2, pindel, varscan2
- CD36 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 39/675 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CDHR3 | c.2027G>T p.S676I | Missense Mutation (SNP) | VAF 87/270 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- CDK9 | c.735C>A p.C245* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- CFAP43 | c.3548_3587del p.E1183Afs*9 | Frame Shift Del (DEL) | VAF 45/241 reads (19%) | called by mutect2, pindel
- CFAP54 | c.7486A>G p.K2496E | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CHAF1A | c.2513A>G p.Q838R | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- CLN3 | c.498_514del p.A167Pfs*39 (on ENST00000360019 / NM_001286104.2; = p.A191Pfs*39 on NM_000086.2) | Frame Shift Del (DEL) | VAF 67/186 reads (36%) | called by mutect2, varscan2
- CNR1 | c.647T>C p.I216T | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CNTNAP5 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 80/138 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CRAT | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2
- CREB3 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- CSTF2 | c.1684A>C p.S562R | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CWF19L1 | c.525del p.K175Nfs*14 | Frame Shift Del (DEL) | VAF 59/155 reads (38%) | called by mutect2, pindel, varscan2
- DAPK1 | c.3822del p.Y1275Tfs*31 | Frame Shift Del (DEL) | VAF 30/162 reads (19%) | called by mutect2, pindel, varscan2
- DCP1B | c.548dup p.I184Dfs*9 | Frame Shift Ins (INS) | VAF 128/312 reads (41%) | called by mutect2, pindel, varscan2
- DDX60 | c.1211T>C p.I404T | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); called by muse, mutect2
- DGKG | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- DHRS7C | c.289G>A p.V97I (on ENST00000330255 / NM_001220493.2; = p.V96I on NM_001105571.3) | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- DIAPH2 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
- DKK2 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 87/170 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- DNAJB2 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNMT1 | c.3758+3A>G | Splice Region (SNP) | VAF 90/240 reads (38%) | called by muse, mutect2, varscan2
- DPP3 | c.1332T>A p.D444E | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DRGX | c.128A>G p.Q43R | Missense Mutation (SNP) | VAF 90/174 reads (52%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DTX2 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- DUSP11 | c.575-1_577del p.X192_splice | Splice Site (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- DYRK4 | c.48C>G p.S16R | Missense Mutation (SNP) | VAF 50/377 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- EBF3 | c.36dup p.T13Dfs*65 | Frame Shift Ins (INS) | VAF 25/52 reads (48%) | called by mutect2, pindel, varscan2
- EFCAB6 | c.4072G>A p.D1358N | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- ELF2 | c.796C>T p.R266* (on ENST00000379550 / NM_001331036.2; = p.R206* on NM_006874.4) | Nonsense Mutation (SNP) | VAF 41/126 reads (33%) | called by muse, mutect2, varscan2
- EML3 | c.1110G>C p.A370= | Splice Region (SNP) | VAF 51/112 reads (46%) | called by muse, mutect2, varscan2
- ENKD1 | c.987G>T p.E329D | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- EPHX1 | c.183+2T>C p.X61_splice | Splice Site (SNP) | VAF 83/194 reads (43%) | called by muse, mutect2, varscan2
- ERICH3 | c.2147del p.K716Rfs*17 | Frame Shift Del (DEL) | VAF 59/137 reads (43%) | called by mutect2, pindel, varscan2
- EZR | c.1428dup p.V477Rfs*16 | Frame Shift Ins (INS) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- FAM209A | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- FAM228A | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- FANCD2 | c.2534T>C p.V845A | Missense Mutation (SNP) | VAF 14/347 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- FBXO28 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FBXO46 | c.446del p.G149Afs*51 | Frame Shift Del (DEL) | VAF 25/39 reads (64%) | called by mutect2, pindel, varscan2
- FLNC | c.4928-2A>G p.X1643_splice | Splice Site (SNP) | VAF 44/170 reads (26%) | called by muse, mutect2, varscan2
- FRMD1 | c.1028A>G p.Q343R | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- FSIP2 | c.7410G>A p.M2470I | Missense Mutation (SNP) | VAF 137/191 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- G6PD | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GABRR1 | c.490A>G p.K164E | Missense Mutation (SNP) | VAF 15/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GALNTL6 | c.1472C>A p.T491K | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.229); called by muse, mutect2
- GAPT | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNPNAT1 | c.162del p.F54Lfs*7 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- GOLGA8M | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 97/184 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- GOLGA8T | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- GPC3 | c.1414C>G p.L472V | Missense Mutation (SNP) | VAF 51/294 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- GYG2 | c.1236+2T>C p.X412_splice | Splice Site (SNP) | VAF 34/56 reads (61%) | called by muse, mutect2, varscan2
- HIPK2 | c.1301T>C p.F434S | Missense Mutation (SNP) | VAF 60/227 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HSD17B4 | c.2238G>T p.M746I (on ENST00000414835 / NM_001199291.3; = p.M721I on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/184 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- HUWE1 | c.12356A>G p.Y4119C | Missense Mutation (SNP) | VAF 94/261 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HYDIN | c.11597A>G p.Q3866R | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- IARS1 | c.1870A>G p.R624G | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNA8 | c.149T>C p.F50S | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- IGSF10 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IKBKG | c.227G>A p.C76Y | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.015); called by mutect2, varscan2
- IL12RB2 | c.142A>G p.N48D | Missense Mutation (SNP) | VAF 80/244 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- INTS5 | c.1037T>G p.V346G | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- INTS7 | c.480del p.F160Lfs*15 | Frame Shift Del (DEL) | VAF 45/154 reads (29%) | called by mutect2, pindel, varscan2
- ITM2A | c.442-9_450del p.X148_splice | Splice Site (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- JAG1 | c.3460T>C p.S1154P | Missense Mutation (SNP) | VAF 154/397 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); called by mutect2, varscan2
- KANSL1 | c.422T>C p.M141T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- KCNN3 | c.243_244insGCCG p.P82Afs*54 | Frame Shift Ins (INS) | VAF 28/152 reads (18%) | called by mutect2, varscan2*
- L3MBTL1 | c.455A>G p.D152G (on ENST00000418998 / NM_001377303.1; = p.D62G on NM_015478.7) | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- LAG3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- LAMB4 | c.2606C>T p.A869V | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LAMP1 | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- LDLRAD3 | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIPC | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 80/139 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- LONRF3 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- LRRC74B | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- LSMEM2 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- MAGEC1 | c.2130del p.P711Lfs*34 | Frame Shift Del (DEL) | VAF 39/170 reads (23%) | called by mutect2, pindel, varscan2
- MAP3K5 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MCM5 | c.712C>G p.H238D | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MEST | c.101del p.P34Lfs*38 | Frame Shift Del (DEL) | VAF 39/138 reads (28%) | called by mutect2, pindel, varscan2
- MID1 | c.1576G>T p.G526W | Missense Mutation (SNP) | VAF 116/381 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MKI67 | c.7367A>T p.D2456V | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- MORC2 | c.2201C>G p.P734R (on ENST00000397641 / NM_001303256.3; = p.P672R on NM_014941.3) | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MOV10L1 | c.3617A>T p.K1206M | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MUC17 | c.12291del p.K4097Nfs*12 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- MYH11 | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH9 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 122/496 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, varscan2
- MYO10 | c.5803A>G p.N1935D | Missense Mutation (SNP) | VAF 63/105 reads (60%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NBAS | c.3451C>T p.P1151S | Missense Mutation (SNP) | VAF 131/325 reads (40%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- NIPBL | c.3710A>G p.Q1237R | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.145); called by muse, mutect2
- NOP56 | c.1280A>G p.Q427R | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- NOTCH2NLA | c.298+2T>C p.X100_splice | Splice Site (SNP) | VAF 18/160 reads (11%) | called by mutect2, varscan2
- NRIP1 | c.1547del p.N516Tfs*11 | Frame Shift Del (DEL) | VAF 88/274 reads (32%) | called by mutect2, pindel, varscan2
- NUDT16 | c.48del p.S17Rfs*30 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- OLA1 | c.987G>T p.Q329H | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- OMD | c.11del p.L4* | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | called by mutect2, pindel, varscan2
- OR2M7 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- OR2T33 | c.845T>C p.L282S | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- OR4P4 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR5A2 | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PABPC1 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH19 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 128/489 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, varscan2
- PCDH7 | c.2414G>A p.R805K | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- PCDHGA4 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 89/154 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEX1 | c.2100C>G p.I700M | Missense Mutation (SNP) | VAF 147/503 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- PEX11A | c.415del p.L139Cfs*8 | Frame Shift Del (DEL) | VAF 60/122 reads (49%) | called by mutect2, pindel, varscan2
- PHF2 | c.432C>G p.F144L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PIWIL1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- PLIN2 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 50/158 reads (32%) | called by muse, varscan2
- PRPF4B | c.746A>T p.Q249L | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PSD | c.2710G>A p.V904M | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- PTPRE | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PUM3 | c.1202A>G p.H401R | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- RAB40C | c.811del p.Q271Rfs*58 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, varscan2
- RAD50 | c.2824G>C p.D942H | Missense Mutation (SNP) | VAF 175/236 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- RHBDD3 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RMND1 | c.1041A>C p.E347D | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RNF165 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 92/114 reads (81%) | called by muse, mutect2, varscan2
- RPS26 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 120/356 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- RUSC2 | c.2581C>T p.R861* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- SCAP | c.985A>G p.M329V | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SELENOV | c.672del p.I225Ffs*40 | Frame Shift Del (DEL) | VAF 26/122 reads (21%) | called by mutect2, pindel, varscan2
- SFRP4 | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- SH2B1 | c.1400T>C p.L467P | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SLC2A1 | c.867T>C p.A289= | Splice Region (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- SLC33A1 | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 19/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- SLC9A3R1 | c.53A>C p.E18A | Missense Mutation (SNP) | VAF 76/129 reads (59%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SNAI2 | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 35/383 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2
- SOX14 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 99/245 reads (40%) | called by muse, mutect2, varscan2
- SSTR3 | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ST3GAL1 | c.492C>G p.D164E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | PolyPhen benign (0.177); called by muse, mutect2, varscan2
- STK10 | c.249G>C p.E83D | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STRC | c.4598G>T p.R1533M | Missense Mutation (SNP) | VAF 88/157 reads (56%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SUPT7L | c.451T>C p.W151R | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- TAF1 | c.963G>T p.W321C (on ENST00000373790 / NM_138923.4; = p.W342C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D10B | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TBC1D8B | c.141dup p.G48Wfs*4 | Frame Shift Ins (INS) | VAF 30/128 reads (23%) | called by mutect2, pindel, varscan2
- TCHP | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX33 | c.835A>C p.K279Q (on ENST00000381821 / NM_001163857.2; = p.K194Q on NM_178552.4) | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TGFBR3 | c.841T>C p.W281R | Missense Mutation (SNP) | VAF 138/376 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THOC6 | c.412-8C>A | Splice Region (SNP) | VAF 65/167 reads (39%) | called by muse, mutect2, varscan2
- TMEM126A | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 130/585 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- TNFAIP3 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 82/305 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by mutect2, varscan2
- TNRC6C | c.4781C>G p.A1594G | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TONSL | c.220G>T p.G74* | Nonsense Mutation (SNP) | VAF 37/190 reads (19%) | called by muse, mutect2, varscan2
- TPP1 | c.687G>C p.Q229H | Missense Mutation (SNP) | VAF 68/117 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRPM5 | c.2708A>C p.E903A | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TSEN54 | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC26 | c.1312+2T>C p.X438_splice | Splice Site (SNP) | VAF 63/253 reads (25%) | called by muse, mutect2, varscan2
- USP27X | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- USP32 | c.3935dup p.L1312Ffs*12 | Frame Shift Ins (INS) | VAF 74/210 reads (35%) | called by mutect2, pindel, varscan2
- VARS2 | c.1310T>C p.V437A | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.055); called by muse, mutect2
- WASHC4 | c.2777T>C p.V926A | Missense Mutation (SNP) | VAF 118/272 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, varscan2
- WDR13 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- WDR97 | c.3498del p.L1166Ffs*68 | Frame Shift Del (DEL) | VAF 86/237 reads (36%) | called by mutect2, pindel, varscan2
- WNK1 | c.4385del p.G1462Afs*13 (on ENST00000315939 / NM_018979.4; = p.G1215Afs*13 on NM_014823.3) | Frame Shift Del (DEL) | VAF 119/473 reads (25%) | called by mutect2, pindel, varscan2
- WNK2 | c.4222G>T p.A1408S (on ENST00000297954 / NM_001282394.1; = p.A1371S on NM_006648.3) | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- WWP1 | c.2446A>G p.T816A | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- XIRP2 | c.3196T>C p.W1066R (on ENST00000628543; = p.W1241R on NM_152381.6) | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- XRN2 | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 95/291 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- YIPF6 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZC3HC1 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2, varscan2
- ZFPM2 | c.1642del p.A548Lfs*8 | Frame Shift Del (DEL) | VAF 147/650 reads (23%) | called by mutect2, pindel, varscan2
- ZNF2 | c.205G>T p.G69W | Missense Mutation (SNP) | VAF 81/132 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZNF35 | c.1111T>G p.F371V | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF646 | c.4929G>T p.E1643D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF674 | c.1370T>A p.I457N | Missense Mutation (SNP) | VAF 99/275 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF862 | c.852_866del p.D284_K288del | In Frame Del (DEL) | VAF 56/175 reads (32%) | called by mutect2, pindel, varscan2
- ZNF90 | c.287A>C p.Q96P | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ALPP | c.15C>T p.C5= | Silent (SNP) | VAF 27/52 reads (52%) | called by muse, mutect2, varscan2
- ANP32B | c.465A>G p.A155= | Silent (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- ANXA3 | c.156G>A p.Q52= | Silent (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- BAG4 | c.1302A>G p.V434= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as rs955822998; called by muse, mutect2, varscan2
- BCOR | c.2400C>T p.S800= | Silent (SNP) | VAF 165/476 reads (35%) | catalogued as rs1400543272; called by muse, mutect2, varscan2
- CACNG2 | c.945A>C p.T315= | Silent (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- CAPN15 | c.2721C>T p.G907= | Silent (SNP) | VAF 47/68 reads (69%) | catalogued as rs772978454; called by muse, mutect2, varscan2
- CCN4 | c.264G>A p.T88= | Silent (SNP) | VAF 98/273 reads (36%) | catalogued as rs906759468, COSV51534579; called by muse, mutect2, varscan2
- CCR2 | c.42C>T p.N14= | Silent (SNP) | VAF 79/141 reads (56%) | catalogued as rs192039364; called by muse, mutect2, varscan2
- CDKAL1 | c.831A>G p.K277= | Silent (SNP) | VAF 44/139 reads (32%) | called by muse, mutect2, varscan2
- CREG2 | c.528A>G p.T176= | Silent (SNP) | VAF 52/167 reads (31%) | called by muse, mutect2, varscan2
- CTNNAL1 | c.531T>C p.T177= | Silent (SNP) | VAF 64/165 reads (39%) | catalogued as rs544864293; called by muse, mutect2, varscan2
- CYSRT1 | c.543T>C p.C181= (on ENST00000409414; = p.C141= on NM_199001.5) | Silent (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- DAB1 | c.1728G>A p.E576= (on ENST00000371231; = p.E543= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- DBH | c.252C>T p.G84= | Silent (SNP) | VAF 102/169 reads (60%) | catalogued as rs570356950, COSV55041742; called by muse, mutect2, varscan2
- DCHS2 | c.1059G>A p.A353= | Silent (SNP) | VAF 79/126 reads (63%) | catalogued as COSV59729549, COSV59735569; called by muse, mutect2, varscan2
- DEDD | c.333T>C p.P111= | Silent (SNP) | VAF 14/68 reads (21%) | called by mutect2, varscan2
- DIABLO | c.378G>A p.Q126= (on ENST00000443649 / NM_001278303.1; = p.Q199= on NM_019887.6) | Silent (SNP) | VAF 87/394 reads (22%) | called by muse, mutect2, varscan2
- DLL1 | c.1731G>A p.R577= | Silent (SNP) | VAF 72/402 reads (18%) | catalogued as COSV64537923; called by muse, mutect2, varscan2
- DPEP1 | c.30T>C p.L10= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- EGR2 | c.1182T>C p.G394= | Silent (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- ENTPD1 | c.693G>A p.E231= | Silent (SNP) | VAF 114/316 reads (36%) | called by muse, mutect2, varscan2
- EP400 | c.3270C>T p.I1090= | Silent (SNP) | VAF 49/127 reads (39%) | called by muse, mutect2, varscan2
- FAM120B | c.2232G>A p.A744= | Silent (SNP) | VAF 83/267 reads (31%) | catalogued as rs369790588; called by muse, mutect2, varscan2
- FAM120B | c.2307C>T p.A769= | Silent (SNP) | VAF 28/428 reads (7%) | catalogued as rs747035229, COSV99379196; called by muse, mutect2
- FAM209A | c.48C>T p.C16= | Silent (SNP) | VAF 64/166 reads (39%) | called by muse, mutect2, varscan2
- FGD6 | c.3354T>C p.Y1118= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs370105836; called by mutect2, varscan2
- FUT2 | c.573G>A p.R191= | Silent (SNP) | VAF 88/240 reads (37%) | called by muse, varscan2
- GATAD2B | c.1632C>T p.G544= | Silent (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- GON4L | c.5565T>C p.H1855= | Silent (SNP) | VAF 59/281 reads (21%) | called by muse, mutect2, varscan2
- H2BC15 | c.357C>T p.V119= | Silent (SNP) | VAF 93/177 reads (53%) | catalogued as rs370729564; called by muse, mutect2, varscan2
- HBA2 | c.267G>A p.A89= | Silent (SNP) | VAF 65/158 reads (41%) | called by muse, mutect2, varscan2
- HTRA4 | c.243C>T p.G81= | Silent (SNP) | VAF 14/26 reads (54%) | called by muse, varscan2
- IL1RN | c.273C>T p.C91= (on ENST00000409930 / NM_173842.3; = p.C73= on NM_000577.5) | Silent (SNP) | VAF 75/223 reads (34%) | catalogued as rs114573615; called by muse, mutect2, varscan2
- ING1 | c.843G>A p.A281= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1397561064, COSV58166343; called by muse, mutect2, varscan2
- INPP5J | c.1107C>A p.A369= | Silent (SNP) | VAF 48/204 reads (24%) | called by muse, mutect2, varscan2
- ITGAD | c.3099C>T p.S1033= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as rs757764435; called by muse, mutect2, varscan2
- ITIH5 | c.2748C>T p.D916= | Silent (SNP) | VAF 137/401 reads (34%) | catalogued as rs143775699; called by muse, mutect2, varscan2
- KCNH7 | c.2445T>C p.Y815= | Silent (SNP) | VAF 171/226 reads (76%) | catalogued as COSV59811050; called by muse, mutect2, varscan2
- KCNMA1 | c.1500G>A p.A500= | Silent (SNP) | VAF 79/198 reads (40%) | catalogued as rs201400928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF1A | c.6C>T p.A2= | Silent (SNP) | VAF 40/63 reads (63%) | catalogued as rs371266160; called by muse, mutect2, varscan2
- MAFK | c.384C>A p.P128= | Silent (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- MAGEL2 | c.214C>T p.L72= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV58568502; called by muse, mutect2, varscan2
- MCPH1 | c.2283G>A p.A761= | Silent (SNP) | VAF 95/175 reads (54%) | called by muse, mutect2, varscan2
- MED17 | c.891G>T p.A297= | Silent (SNP) | VAF 104/308 reads (34%) | called by muse, mutect2, varscan2
- MEGF6 | c.2076G>T p.G692= | Silent (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- MISP | c.198G>A p.V66= | Silent (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- MKNK1 | c.906C>T p.G302= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, varscan2
- MOV10L1 | c.2925C>T p.H975= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs150542460; called by muse, mutect2, varscan2
- MPV17L | c.465C>A p.V155= (on ENST00000396385 / NM_001128423.2; = p.L132M on NM_173803.4) | Silent (SNP) | VAF 66/160 reads (41%) | catalogued as COSV55009192; called by muse, mutect2, varscan2
- MRPS5 | c.948C>T p.C316= | Silent (SNP) | VAF 65/148 reads (44%) | catalogued as rs1232006359; called by muse, mutect2, varscan2
- NFIC | c.219G>A p.A73= | Silent (SNP) | VAF 154/396 reads (39%) | catalogued as rs750273583, COSV59411159; called by muse, mutect2, varscan2
- OTOG | c.975C>A p.P325= | Silent (SNP) | VAF 62/103 reads (60%) | called by muse, varscan2
- PCDH19 | c.45G>A p.L15= | Silent (SNP) | VAF 53/233 reads (23%) | called by muse, mutect2, varscan2
- PCED1B | c.1182A>G p.P394= | Silent (SNP) | VAF 48/139 reads (35%) | called by muse, mutect2, varscan2
- PEDS1 | c.357G>A p.E119= | Silent (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- PFKP | c.1800T>G p.A600= | Silent (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2
- PGM5 | c.195C>T p.G65= | Silent (SNP) | VAF 40/146 reads (27%) | catalogued as rs1563977953; called by muse, mutect2, varscan2
- PLD5 | c.417A>G p.L139= (on ENST00000442594; = p.L77= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/219 reads (21%) | catalogued as rs780474716; called by muse, mutect2, varscan2
- PPRC1 | c.417T>C p.D139= | Silent (SNP) | VAF 42/113 reads (37%) | called by muse, mutect2, varscan2
- PRKDC | c.12234G>T p.V4078= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- PTBP2 | c.1266T>C p.T422= (on ENST00000426398 / NM_001300986.2; = p.T414= on NM_021190.4) | Silent (SNP) | VAF 86/226 reads (38%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.3111T>C p.D1037= | Silent (SNP) | VAF 90/376 reads (24%) | called by muse, mutect2, varscan2
- RAB11FIP1 | c.3132G>A p.E1044= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs1165926898; called by muse, mutect2, varscan2
- RECQL4 | c.2391C>T p.S797= | Silent (SNP) | VAF 62/274 reads (23%) | called by muse, mutect2, varscan2
- RFPL1 | c.315A>G p.E105= | Silent (SNP) | VAF 56/219 reads (26%) | called by muse, mutect2, varscan2
- RFX1 | c.1986G>A p.L662= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs1368636845, COSV99586117; called by muse, mutect2, varscan2
- RNF183 | c.510C>A p.I170= | Silent (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- SALL4 | c.114C>T p.P38= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs1319172990, COSV53855404; called by muse, mutect2, varscan2
- SCML2 | c.540T>C p.A180= | Silent (SNP) | VAF 24/136 reads (18%) | called by muse, mutect2, varscan2
- SCN4A | c.4518C>T p.Y1506= | Silent (SNP) | VAF 106/299 reads (35%) | catalogued as rs777015227, COSV71125982; called by muse, mutect2, varscan2
- SCUBE3 | c.2202T>C p.H734= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as rs779410189; called by muse, mutect2, varscan2
- SCYL1 | c.2097G>A p.E699= | Silent (SNP) | VAF 63/147 reads (43%) | called by muse, mutect2, varscan2
- SEMA3D | c.1182G>A p.R394= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV52391220; called by muse, mutect2, varscan2
- SH2B1 | c.168G>A p.A56= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as rs769613563; called by muse, mutect2, varscan2
- SIPA1L3 | c.759C>G p.G253= | Silent (SNP) | VAF 58/116 reads (50%) | catalogued as rs1169786424, COSV55912715, COSV55918017; called by mutect2, varscan2
- SIPA1L3 | c.5028G>C p.L1676= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV55910682; called by muse, mutect2, varscan2
- SLC12A3 | c.912G>A p.T304= | Silent (SNP) | VAF 93/153 reads (61%) | catalogued as rs371332701; called by muse, mutect2, varscan2
- SLC5A8 | c.423G>A p.L141= | Silent (SNP) | VAF 41/128 reads (32%) | called by muse, mutect2, varscan2
- SLC9A9 | c.1566T>C p.S522= | Silent (SNP) | VAF 41/257 reads (16%) | catalogued as rs1283060669; called by muse, mutect2, varscan2
- SPACA3 | c.306C>T p.F102= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as rs775934021, COSV52191672; called by muse, mutect2, varscan2
- SPAG17 | c.4200A>T p.G1400= | Silent (SNP) | VAF 108/306 reads (35%) | catalogued as COSV100310988; called by muse, mutect2, varscan2
- SPTB | c.2464C>A p.R822= | Silent (SNP) | VAF 83/123 reads (67%) | catalogued as COSV101071991, COSV67630731; called by muse, mutect2, varscan2
- SPTBN4 | c.3021G>C p.R1007= | Silent (SNP) | VAF 51/105 reads (49%) | called by muse, mutect2, varscan2
- SRPRA | c.672T>C p.G224= | Silent (SNP) | VAF 44/104 reads (42%) | called by muse, mutect2, varscan2
- ST18 | c.2370C>T p.S790= | Silent (SNP) | VAF 73/192 reads (38%) | catalogued as rs775413941; called by muse, mutect2, varscan2
- SYNE1 | c.24883C>T p.L8295= (on ENST00000367255 / NM_182961.4; = p.L8224= on NM_033071.3) | Silent (SNP) | VAF 55/188 reads (29%) | called by muse, mutect2, varscan2
- TAF1C | c.882C>T p.C294= | Silent (SNP) | VAF 61/127 reads (48%) | called by muse, mutect2, varscan2
- TAT | c.48A>T p.S16= | Silent (SNP) | VAF 93/187 reads (50%) | called by muse, mutect2, varscan2
- TBC1D9B | c.9G>A p.L3= | Silent (SNP) | VAF 40/52 reads (77%) | catalogued as rs1429124586; called by muse, varscan2
- TLN1 | c.6441G>A p.E2147= | Silent (SNP) | VAF 71/198 reads (36%) | called by muse, mutect2, varscan2
- TMEM181 | c.801G>C p.P267= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV65564529, COSV65566486; called by muse, mutect2, varscan2
- TMEM87A | c.733C>T p.L245= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as rs138319789; called by muse, mutect2, varscan2
- TPTE | c.1239A>C p.I413= (on ENST00000618007 / NM_199261.4; = p.I395= on NM_199259.4) | Silent (SNP) | VAF 79/488 reads (16%) | catalogued as rs777436958; called by muse, mutect2, varscan2
- TRAPPC5 | c.507G>A p.T169= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs749805705, COSV58039872; called by muse, mutect2, varscan2
- TRHDE | c.2961G>T p.G987= | Silent (SNP) | VAF 43/142 reads (30%) | called by muse, mutect2, varscan2
- TRPS1 | c.138G>A p.T46= (on ENST00000220888 / NM_001330599.2; = p.T59= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 150/613 reads (24%) | catalogued as rs781105371; called by muse, mutect2, varscan2
- TTLL4 | c.1944T>C p.P648= | Silent (SNP) | VAF 69/109 reads (63%) | catalogued as COSV99293182; called by muse, mutect2, varscan2
- TTN | c.38481A>G p.S12827= (on ENST00000591111; = p.S5403= on NM_003319.4) | Silent (SNP) | VAF 21/232 reads (9%) | called by muse, mutect2
- USF3 | c.1380G>A p.E460= | Silent (SNP) | VAF 69/177 reads (39%) | catalogued as rs1300224652, COSV57075145; called by muse, mutect2, varscan2
- VSTM1 | c.21C>T p.S7= | Silent (SNP) | VAF 82/105 reads (78%) | catalogued as rs376235740; called by muse, mutect2, varscan2
- WIPF2 | c.471G>A p.P157= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as rs781328877, COSV60276361; called by muse, mutect2, varscan2
- WNT3 | c.1017C>T p.Y339= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as rs139160780; called by muse, mutect2, varscan2
- ZNF410 | c.1173A>G p.V391= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- ZNF490 | c.552T>C p.N184= | Silent (SNP) | VAF 91/231 reads (39%) | called by muse, mutect2, varscan2
- ZNF592 | c.465T>C p.D155= | Silent (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2
- ZNF607 | c.534C>G p.V178= | Silent (SNP) | VAF 72/272 reads (26%) | called by muse, mutect2, varscan2
- ZNF615 | c.1473A>G p.K491= | Silent (SNP) | VAF 60/182 reads (33%) | called by muse, mutect2, varscan2
- ZNF80 | c.405C>T p.C135= | Silent (SNP) | VAF 89/228 reads (39%) | catalogued as COSV100351880; called by muse, mutect2, varscan2
- AC011330.1 | n.1058T>C | RNA (SNP) | VAF 62/100 reads (62%) | called by muse, mutect2, varscan2
- AC078880.2 | n.273C>T | RNA (SNP) | VAF 125/290 reads (43%) | called by muse, mutect2, varscan2
- AC244394.2 | n.1380C>T | RNA (SNP) | VAF 40/240 reads (17%) | catalogued as rs750956372; called by muse, mutect2, varscan2
- AFF2 | c.1041+56457G>A | Intron (SNP) | VAF 59/213 reads (28%) | catalogued as rs782443496; called by muse, mutect2, varscan2
- AL139039.3 | chr6:10509158 G>A | 3'Flank (SNP) | VAF 22/130 reads (17%) | called by muse, mutect2
- ALDH1L1 | c.1983-62G>C | Intron (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- C17orf49 | chr17:7017925 del C | 3'Flank (DEL) | VAF 12/15 reads (80%) | catalogued as rs1219716735; called by mutect2, varscan2
- C2CD5 | c.2534-1424C>T | Intron (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- CACTIN | c.*409del | 3'UTR (DEL) | VAF 52/146 reads (36%) | catalogued as rs1568288873; called by mutect2, varscan2
- CAMK2G | c.1191-25C>T | Intron (SNP) | VAF 12/50 reads (24%) | catalogued as rs1479258170; called by muse, mutect2, varscan2
- CCDC73 | c.429+20T>C | Intron (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- DENND10P1 | n.666T>C | RNA (SNP) | VAF 16/550 reads (3%) | called by muse, mutect2
- DENND4B | c.-3del | 5'UTR (DEL) | VAF 24/139 reads (17%) | catalogued as rs770832731; called by mutect2, varscan2
- DHRS4 | chr14:23970267 del C | 3'Flank (DEL) | VAF 16/29 reads (55%) | called by mutect2, varscan2
- DHRS4-AS1 | n.2966T>C | RNA (SNP) | VAF 44/70 reads (63%) | catalogued as rs1164995045; called by muse, mutect2
- DIABLO | c.97-44T>C | Intron (SNP) | VAF 28/234 reads (12%) | catalogued as rs888512007; called by muse, mutect2, varscan2
- DMTN | c.*811dup | 3'UTR (INS) | VAF 20/38 reads (53%) | catalogued as rs762996432; called by mutect2, varscan2
- ELN | c.889+30T>C | Intron (SNP) | VAF 134/306 reads (44%) | called by muse, mutect2, varscan2
- ELP2 | c.289-42del | Intron (DEL) | VAF 37/328 reads (11%) | catalogued as rs761640327; called by mutect2, varscan2
- FAM153CP | chr5:178055677 A>G | 3'Flank (SNP) | VAF 108/384 reads (28%) | called by mutect2, varscan2
- FAS | c.*1017del | 3'UTR (DEL) | VAF 114/353 reads (32%) | called by mutect2, pindel, varscan2
- FECH | c.314+51G>A | Intron (SNP) | VAF 55/190 reads (29%) | called by muse, mutect2, varscan2
- FGFR4 | c.92-10C>T | Intron (SNP) | VAF 110/144 reads (76%) | called by muse, mutect2, varscan2
- G6PD | c.1052-22G>T | Intron (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- GAB3 | c.1645-812T>C | Intron (SNP) | VAF 22/115 reads (19%) | called by muse, mutect2, varscan2
- GIGYF1 | c.-248T>C | 5'UTR (SNP) | VAF 59/104 reads (57%) | called by muse, mutect2, varscan2
- GOLGA8R | c.348+73C>T | Intron (SNP) | VAF 57/92 reads (62%) | catalogued as rs1417891196; called by muse, mutect2, varscan2
- GPX3 | c.460-20T>C | Intron (SNP) | VAF 98/160 reads (61%) | called by muse, mutect2, varscan2
- GRIK2 | c.2563-2484A>G | Intron (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- HMGA1 | c.*235T>C | 3'UTR (SNP) | VAF 14/56 reads (25%) | catalogued as rs1561878568; called by muse, varscan2
- IFT80 | c.1315+1645del | Intron (DEL) | VAF 40/106 reads (38%) | catalogued as rs752029701; called by mutect2, varscan2
- INTS1 | c.*33G>A | 3'UTR (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- IQGAP1 | c.4161-18T>C | Intron (SNP) | VAF 61/84 reads (73%) | called by muse, mutect2, varscan2
- KAZN | c.-32_-28del | 5'UTR (DEL) | VAF 14/24 reads (58%) | called by mutect2, pindel, varscan2
- LBHD1 | c.617-567C>G | Intron (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- LYSMD4 | c.282+358A>G | Intron (SNP) | VAF 93/139 reads (67%) | catalogued as COSV60387176; called by muse, mutect2, varscan2
- MAGEC3 | c.910-496G>A | Intron (SNP) | VAF 33/114 reads (29%) | called by muse, mutect2, varscan2
- MAN1B1 | c.1255-193G>T | Intron (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5610C>G | Intron (SNP) | VAF 65/173 reads (38%) | called by muse, mutect2, varscan2
- MIR570 | n.75C>G | RNA (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- MPND | c.1236+550A>G | Intron (SNP) | VAF 45/132 reads (34%) | catalogued as rs1376375666; called by muse, mutect2, varscan2
- NDUFS8 | c.-1+162_-1+163insCCTCAGGGCGCCGGC | Intron (INS) | VAF 32/101 reads (32%) | catalogued as rs11276215; called by pindel, varscan2
- NOC2LP2 | n.1127C>A | RNA (SNP) | VAF 30/218 reads (14%) | called by muse, mutect2
- NR3C1 | c.*2512A>G | 3'UTR (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- OAZ3 | chr1:151763163 C>T | 5'Flank (SNP) | VAF 48/201 reads (24%) | called by muse, mutect2, varscan2
- OR52A4P | chr11:5120791 del A | 3'Flank (DEL) | VAF 20/43 reads (47%) | catalogued as rs769032953; called by mutect2, varscan2
- PLAAT4 | c.387+13_387+14del | Intron (DEL) | VAF 40/138 reads (29%) | catalogued as rs771102532; called by pindel, varscan2
- RAB18 | c.*956del | 3'UTR (DEL) | VAF 78/128 reads (61%) | catalogued as rs909736212; called by mutect2, varscan2
- RAX2 | c.-50del | 5'UTR (DEL) | VAF 18/42 reads (43%) | catalogued as rs559035106; called by mutect2, pindel
- RBM48 | c.1017+96del | Intron (DEL) | VAF 52/207 reads (25%) | called by mutect2, varscan2
- RHOF | chr12:121797511 A>G | 5'Flank (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.2022G>A | RNA (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- RPL12 | c.493-12del | Intron (DEL) | VAF 52/82 reads (63%) | catalogued as rs536891934; called by mutect2, varscan2
- RPL13A | c.256+90A>C | Intron (SNP) | VAF 72/213 reads (34%) | catalogued as COSV52619121; called by muse, mutect2, varscan2
- RTL8B | c.*557G>T | 3'UTR (SNP) | VAF 40/192 reads (21%) | called by muse, mutect2, varscan2
- SEC14L2 | c.-60C>T | 5'UTR (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- SEPTIN1 | c.*220C>A | 3'UTR (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- SF3A2 | c.199-17T>C | Intron (SNP) | VAF 54/141 reads (38%) | called by muse, mutect2, varscan2
- SHLD2P1 | n.1960C>T | RNA (SNP) | VAF 26/200 reads (13%) | catalogued as rs1438841530; called by muse, varscan2
- SLC16A14 | c.1381+29G>T | Intron (SNP) | VAF 29/46 reads (63%) | called by muse, mutect2, varscan2
- SLC30A3 | c.*82G>A | 3'UTR (SNP) | VAF 24/66 reads (36%) | catalogued as rs759979836, COSV99273649; called by muse, mutect2, varscan2
- SLC3A1 | c.-21G>A | 5'UTR (SNP) | VAF 83/142 reads (58%) | catalogued as rs746039602, COSV99577364; called by muse, mutect2, varscan2
- SPATA31C1 | n.2071C>A | RNA (SNP) | VAF 144/544 reads (26%) | called by muse, mutect2, varscan2
- SPTLC1 | c.*46G>T | 3'UTR (SNP) | VAF 57/228 reads (25%) | called by muse, mutect2, varscan2
- SRSF11 | c.338-415T>G | Intron (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- SVIL2P | n.1851G>T | RNA (SNP) | VAF 72/227 reads (32%) | called by muse, mutect2, varscan2
- SYT14 | chr1:210164287 del A | 3'Flank (DEL) | VAF 17/32 reads (53%) | catalogued as rs201868266; called by mutect2, varscan2
- TAOK2 | c.*410G>A | 3'UTR (SNP) | VAF 28/112 reads (25%) | catalogued as rs1192258991, COSV99663021; called by muse, mutect2, varscan2
- TFAP2B | c.*16del | 3'UTR (DEL) | VAF 69/202 reads (34%) | catalogued as rs747434951; called by mutect2, pindel, varscan2
- TMEM167A | c.114-20del | Intron (DEL) | VAF 66/126 reads (52%) | catalogued as rs769300701; called by mutect2, pindel, varscan2
- TMEM71 | c.*11G>A | 3'UTR (SNP) | VAF 94/223 reads (42%) | called by muse, mutect2, varscan2
- TP63 | c.325-18527G>A | Intron (SNP) | VAF 39/106 reads (37%) | catalogued as COSV53224277; called by muse, mutect2, varscan2
- TSHZ2 | c.41-67864del | Intron (DEL) | VAF 40/104 reads (38%) | called by mutect2, varscan2
- TTK | c.139+136T>C | Intron (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2
- UBE2DNL | n.493C>A | RNA (SNP) | VAF 47/214 reads (22%) | called by muse, mutect2, varscan2
- UBR1 | chr15:43106054 C>A | 5'Flank (SNP) | VAF 107/202 reads (53%) | catalogued as rs1248200676; called by muse, mutect2, varscan2
- UROD | c.*45C>T | 3'UTR (SNP) | VAF 83/228 reads (36%) | catalogued as rs371078664; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UXS1 | c.1028-199C>T | Intron (SNP) | VAF 42/207 reads (20%) | called by muse, mutect2, varscan2
- VPS35L | chr16:19555667 G>T | 5'Flank (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- VWA3A | c.350+41T>G | Intron (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- ZDHHC20 | c.*1636C>T | 3'UTR (SNP) | VAF 27/96 reads (28%) | catalogued as rs1390666326; called by muse, mutect2, varscan2
- ZFHX3 | c.-1062C>T | 5'UTR (SNP) | VAF 31/59 reads (53%) | catalogued as rs753921260; called by muse, mutect2, varscan2
- ZNF322P1 | n.440G>A | RNA (SNP) | VAF 109/512 reads (21%) | catalogued as rs754789172; called by muse, mutect2, varscan2
